Surgical pathology report (de-identified scan), TCGA case TCGA-HZ-7919, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HZ-7919-01A (Primary Tumor).

[page 1 of 3]
Results

GROSS AND MICROSCOPIC SURGICAL PANEL

Specimen Information

Collection Date and Time

Component Results

SURGICAL PANEL:

SURGICAL PATHOLOGY REPORT

LAB:

Phone

Final Report

DIAGNOSIS

PANCREAS, DUODENUM, STOMACH, AND GALLBLADDER, WHIPPLE RESECTION AND CHOLECYSTECTOMY:

1. Invasive moderately differentiated ductal adenocarcinoma, characterized by:
- a. Tumor size: 4.0 x 3.0 x 1.8 cm
- b. Tumor arises in pancreatic head from background IPMN with high grade dysplasia
- c. Tumor invades beyond the pancreas and involves duodenum
2. Multiple (2 of 10) regional lymph nodes are positive for metastatic adenocarcinoma
3. Surgical margins are involved by adenocarcinoma at the portal vein groove and microscopically at the retroperitoneal margin
4. Gallbladder with chronic cholecystitis and cholesterosis
5. See staging parameters

COMMENT

Case number:

Patient name:

Staging parameters include data from the following case(s)

Final TNM: pT3N1M0

stage: IIB

MACROSCOPIC

SPECIMEN TYPE

Whipple, Standard

TUMOR SITE

Pancreatic head

TUMOR SIZE

4.0 X 3.0 X 1.8 cm

MICROSCOPIC

HISTOLOGIC TYPE

Ductal Adenocarcinoma

HISTOLOGIC GRADE

G2: (moderately differentiated) of G4

MARGINS - PANCREATODUODENECTOMY

Involved by invasive carcinoma

Location(s): Pancreatic retroperitoneal, Portal Vein Groove

Margin(s) evaluated: Proximal (stomach), Distal (duodenum),

Pancreatic retroperitoneal, Bile duct, Distal pancreatic,

Portal Vein Groove, Pancreatic uncinata

[page 2 of 3]
LYMPHATIC/VASCULAR INVASION

Present: Lymph-vascular invasion present/Identified

PERINEURAL INVASION

Present

PATHOLOGIC STAGING

EXTENT OF INVASION

pT3. (Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery)

REGIONAL LYMPH NODES

pN1. (Regional lymph node metastasis)

Total nodes: 10

Total positive nodes: 2

DISTANT METASTASIS

pM0. (No distant metastasis)

PATHOLOGIC STAGE SUMMARY

Final TNM: pT3N1M0

stage: IIB

** The pathologic stage presumes no distant metastasis.

Attending Pathologist:

CLINICAL INFORMATION

History of pancreas cancer.

SPECIMEN/GROSS DESCRIPTION

A) SOURCE: Whipple

The specimen is received fresh from the OR labeled "Whipple." It consists of a 4 x 3 x 1.8 cm indurated, markedly ill-defined pancreatic mass found within a Whipple specimen; 6.8 x 4.2 x 2.7 cm pancreatic head, 26 cm in length x 6 cm internal circumference duodenum, 6-9 cm in length and up to 6.3 cm in diameter distal gastrectomy, 10.8 cm in length and 3 cm in diameter intact gallbladder. The pancreas is received previously inked by the surgeon as follows: Pancreatic margin is blue, common bile duct margin is green, portal vein bed is red, retroperitoneal margin is black, and uncinate margin is yellow. Seven representative sections of the tumor are frozen on seven blocks.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "Microscopic focus of tumor at portal vein bed; uncinate negative by < 1 mm; portal vein branch, retroperitoneum, bile duct, distal pancreas margins negative" is rendered by

On cut surface, the tumor is approximately 0.5 cm from the pancreatic margin and 3.2 cm from the common bile duct margin (common bile duct is 5 cm long and 1-2 cm in internal circumference). The pancreatic mass is approximately 0.1 cm from the remaining margins grossly.

The mucosa at the ampulla of Vater displays irregular folds and is vaguely nodular. A discrete mass lesion is not seen on the mucosa. The gallbladder has smooth serosa and bile in its lumen. The common bile duct is received with a blue tubular stent. No inscriptions on the stent are seen.

The cut surfaces of the peripancreatic fat display five possible lymph nodes which measure between 0.8-1.3 cm in greatest dimension. One of the lymph nodes have tan, solid cut surfaces. The cut surfaces of the remaining adipose tissue display four possible lymph nodes within the adipose tissue of the greater curvature. These lymph nodes are fatty and soft and measure between 0.3-1.3 cm in greatest dimension.

[page 3 of 3]
[REDACTED]

Note: The gross specimen was photographed. Tissue was retrieved from the specimen for possible tumor study.

Note: On sectioning of the pancreas, the pancreatic duct is patent measuring 0.3-0.4 cm in diameter.

Representative sections are submitted in 42 cassettes labeled:

- AFS1. Frozen section residue, en face common bile duct margin
- AFS2,3. Frozen section residue, en face pancreatic margin
- AFS4. Frozen section residue, pancreatic mass with uncinate margin
- AFS5. Frozen section residue, pancreatic mass with portal vein bed
- AFS6. Frozen section residue, portal vein branch, en face
- AFS7. Frozen section residue, pancreatic mass with retroperitoneum
- 8,9. Pancreatic mass and portal vein bed near the pancreatic margin
- 10. Pancreatic mass and portal vein bed inferiorly near frozen section #5
- 11. Remainder of the portal vein bed adjacent to cassette 10
- 12-16. Pancreatic mass and black-inked retroperitoneum
- 17,18. Remainder of the possible lymph node submitted in cassette 16
- 19,20. Pancreatic mass and yellow-inked uncinate
- 21,22. Pancreatic mass with common bile duct, ampulla of Vater and duodenum
- 23. Distal pancreas (previously sampled en face margin) with possible pancreatic duct
- 24. Gallbladder wall
- 25,26. En face distal duodenal margin
- 27. Pylorus
- 28. En face proximal margin closest to tumor (less than one-third of the margin)
- 29,30. One lymph node, peripancreatic soft tissue
- 31. Three peripancreatic lymph nodes, two without ink are submitted in toto, and one is inked black and bisected
- 32. One possible peripancreatic lymph node
- 33-35. Peripancreatic soft tissue to include additional possible lymph nodes
- 36,37. Scant attached duodenal adipose tissue to include possible lymph nodes
- 38,39. Lesser curvature, representative sections to include possible lymph nodes
- 40. One lymph node, greater curvature
- 41. One lymph node, greater curvature
- 42. Two lymph nodes, one is inked blue and greater curvature

Tissue was retrieved from the specimen for possible tumor study.

This case is accessioned in [REDACTED]
[REDACTED]

MICROSCOPIC

The microscopic appearance substantiates the diagnosis. Dictation by [REDACTED]
transcribed [REDACTED]

Interpreted at [REDACTED]
[REDACTED] [REDACTED]
[REDACTED]

Lab and Collection
[REDACTED]
[REDACTED]

Source: NCI Genomic Data Commons file 343b471e-9c78-4753-a135-45d8420dfe4c (TCGA-HZ-7919.DB1515C4-E01D-4265-8664-17683C2689A9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).